Gene-level copy-number profile of tumor specimen ALCH-AEOV-TTP1-A from ALCHEMIST case ALCH-AEOV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.1 years (26,348 days).
Specimen ALCH-AEOV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dea0443a-535b-4696-957e-6365311bb48b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/54da0f06-c6af-4e42-acbb-82d40977f434

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,596; copy number 2: 53,979; copy number 3: 1,407; copy number 4: 147; copy number 5: 67; copy number 6: 18; copy number 7: 131; copy number 8: 21; copy number 9: 2; copy number 10: 2; copy number 13: 8; copy number 15: 1; copy number 109: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–2): SHANK2-AS2.
- chr13:111,588,201–111,672,608, 2 genes: AL359649.1, LINC02337.
- chr19:1,241,746–1,244,825, 1 gene: ATP5F1D.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 251 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:121,081,437–121,088,726, 1 gene, copy number 9: AC067960.1.
- chr7:5,620,047–5,781,696, 3 genes, copy number 5: RNF216, RNF216-IT1, MIR6874.
- chr7:5,871,753–5,872,050, 1 gene, copy number 5: RN7SL556P.
- chr8:143,833,270–143,834,063, 1 gene, copy number 15 (within-gene range 4–15): AC234917.1.
- chr8:143,915,153–144,063,965, 7 genes, copy number 5–13 (within-gene range 2–13): PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH.
- chr8:144,082,590–144,108,124, 4 genes, copy number 5–6 (within-gene range 3–6): GPAA1, CYC1, SHARPIN, MAF1.
- chr9:136,483,495–136,486,067, 1 gene, copy number 9 (within-gene range 1–9): C9orf163.
- chr9:136,712,572–136,724,742, 1 gene, copy number 7 (within-gene range 2–7): DIPK1B.
- chr9:136,779,939–136,800,595, 3 genes, copy number 6 (within-gene range 1–6): ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,844,415–136,848,801, 1 gene, copy number 8 (within-gene range 3–9): AJM1.
- chr11:65,423,960–65,466,720, 4 genes, copy number 6: AP000944.2, MIR612, AP000769.4, AP000769.1.
- chr11:65,561,484–65,574,198, 4 genes, copy number 5: AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B.
- chr11:67,627,938–67,629,937, 1 gene, copy number 6: NUDT8.
- chr12:66,767–178,455, 1 gene, copy number 5 (within-gene range 3–5): IQSEC3.
- chr12:137,411–990,053, 22 genes, copy number 5 (within-gene range 3–5): AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr12:65,169,583–75,984,015, 184 genes, copy number 5–13 (broad region; genes not listed).
- chr12:132,457,160–132,460,024, 1 gene, copy number 7: AC079031.1.
- chr16:88,863,333–88,866,660, 1 gene, copy number 6: PABPN1L.
- chr19:1,039,997–1,174,268, 5 genes, copy number 5–6: ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2.
- chr19:1,238,179–1,239,522, 1 gene, copy number 109: AC004221.1.
- chr19:1,248,553–1,279,244, 4 genes, copy number 7–10: MIDN, CIRBP, CIRBP-AS1, FAM174C.

Autosomal genes at a single copy (total copy number 1): 2,593. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
